Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q9, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q9-01A (Primary Tumor).

[page 1 of 4]
		8/31/11

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: OUTPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

7 mm right thyroid nodule positive for papillary thyroid carcinoma.

Specimens Submitted:

- 1: Right paratracheal node (fs)
- 2: Additional right paratracheal node (fs)
- 3: Total thyroidectomy
- 4: Delphial node
- 5: Pretracheal tissue

DIAGNOSIS:

1. Right paratracheal node (fs):

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

2. Additional right paratracheal node (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 3

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 0.6cm.

Size of the largest metastatic focus : 0.3 cm.

Extranodal extension is not identified

Comment: The metastatic focus is best appreciated on the original frozen section slide.

3. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, tall cell variant
with squamous metaplasia

ICD-0-3

carcinoma, papillary, tall cell variant

8344/3

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Site: thyroid, NOS C73.9

Other Tumor Features:

Marked stromal reaction

lw
8/31/11

Tumor Location:

Right lobe

Tumor Size:

[page 2 of 4]
Greatest diameter is 1.5 cm.

Tumor Encapsulation:
Partially surrounded

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Papillary thyroid microcarcinoma, two foci (right lobe: 0.8 cm in greatest dimension; isthmus: less than 0.1 cm in greatest dimension)

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits mild chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified

Comment: The tumor is positive for TTF-1. PAX-8 CK7, thyroglobulin and p63. p53 is non-contributory. Proliferation index labeled with MIB-1 is about 5-10%.
has reviewed the case and agrees with the rendered diagnosis.

4. Delphian lymph node; excision:

- Benign fibroadipose tissue
- No lymph node identified

5. Pretracheal tissue:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CK7	
	TTF-1	
	PAX8.	
	NEG CONT	
	IMM RECUT	
	THYROG	
	MIB-1 (Ki-67)	
	P53	
	4A4/P63	
	RECUT	
	RECUT	

[page 3 of 4]
Gross Description:

1. The specimen is received fresh for intraoperative consultation and is labeled "right paratracheal node". It consists of one piece of tan pink soft tissue, measuring 0.5 x 0.4 x 0.3 cm. Specimen is entirely submitted.

Summary of sections:
FSC- frozen section control

M.D.

2. The specimen is received fresh for intraoperative consultation and is labeled "Additional right paratracheal node". It consists of multiple pieces of tan pink soft tissue, measuring 1.0 x 1.0 x 0.5 cm in aggregate. Three lymph nodes are identified, measuring 0.3 cm, 0.4 cm and 0.6 cm in greatest dimension. Lymph nodes are entirely submitted.

Summary of sections:
FSC- frozen section control

M.D.

3). The specimen is received fresh, labeled "total thyroidectomy stitch marks right lobe of thyroid" and consists of a thyroid weighing 14.5 g. The right lobe measures 5.2 x 2.5 x 1.5 cm, the left lobe measures 3.2 x 1.8 x 1.2 cm and the isthmus measures 1.7 x 0.7 x 0.3 cm. The external surface is covered by a thin fibrous capsule. A 2.5 x 1.5 x 0.4 cm portion of skeletal muscle is attached to the lower right pole. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning of the right lobe reveals 2 nodules in the mid to lower pole, abutting each other. The larger nodule (N1) is 1.5 x 1.3 x 1.2 cm solid whitish, well circumscribed. The smaller nodule (N2) is 0.7 x 0.5 x 0.5 cm, light brown, solid, well circumscribed. Sectioning of the left lobe reveals 2 nodules. One nodule is 0.5 x 0.4 x 0.3 cm, solid, present in the mid pole (N1L). Second nodule is 0.4 x 0.3 x 0.3 cm, solid, well circumscribed, abutting the posterior capsule in the mid aspect. The remaining thyroid parenchyma is red beefy and vaguely nodular. Representative sections from both nodules on the right are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
N1 - larger nodule, right lobe (both nodules in block 1)
N2 - smaller nodule, right lobe
RL - remaining right lobe
RSM - skeletal muscle attached to right lobe
N1L - nodule one left lobe
N2L - nodule two left lobe
LL - remaining left lobe
IS - isthmus

M.D.

4). The specimen is received in formalin, labeled "Delphian node" and consists of a 0.5 x 0.3 x 0.3 cm fragment of tan soft tissue. The specimen is entirely submitted.

Summary of sections:
U - undesignated

5). The specimen is received in formalin, labeled "Pre-tracheal tissue" and consists of a 0.6 x 0.4 x 0.3 cm fragment of tan soft tissue. The specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

[page 4 of 4]
Part 1: Right paratracheal node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Additional right paratracheal node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
2	LL	2
2	N1	2
1	N1L	1
1	N2	1
2	N2L	2
4	RL	4
1	RSM	1

Part 4: Delphial node

Block	Sect. Site	PCs
1	U	1

Part 5: Pretracheal tissue

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right paratracheal node (fs): Benign lymph node
Permanent diagnosis:
2. Frozen section diagnosis: Additional right paratracheal node (fs): Metastatic papillary carcinoma
Permanent diagnosis:

Source: NCI Genomic Data Commons file 9cd04f3a-c1cb-49a8-82a2-f920ac372f24 (TCGA-DJ-A2Q9.37E0F0C8-2294-4F1B-AE62-DB3BD888575B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).